Somatic mutation profile of tumor specimen TCGA-27-2527-01A (aliquot TCGA-27-2527-01A-01D-1494-08) from TCGA case TCGA-27-2527, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 81.1 years (29,619 days).
Specimen TCGA-27-2527-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b708502c-5745-4572-9bbb-c7bb3073a170.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-2527-10A (Blood Derived Normal), aliquot TCGA-27-2527-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/865ea30d-9fdb-4999-8007-d8e09e639d38

The open-access MAF lists 63 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 47, Silent 14, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EXT2 | c.283C>T p.R95C (on ENST00000343631; = p.R128C on NM_000401.3) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs376292686, CM1510402; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 12/112 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADAM29 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs772388824, COSV63659909; called by muse, mutect2, varscan2
- ANK1 | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.051); catalogued as COSV55893617; called by muse, mutect2, varscan2
- ATXN7 | c.2180del p.S727Ffs*24 | Frame Shift Del (DEL) | VAF 21/94 reads (22%) | catalogued as COSV55755249; called by mutect2, pindel, varscan2
- C1S | c.1044T>A p.S348R | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV61070630, COSV61072207; called by muse, mutect2, varscan2
- CACNA1C | c.3224C>T p.T1075M | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs766410481, COSV59763546; called by muse, mutect2, varscan2
- CCDC184 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.027); catalogued as COSV57252451; called by muse, mutect2
- CPXM2 | c.2039G>A p.R680H | Missense Mutation (SNP) | VAF 68/352 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780028739, COSV53869885; called by muse, mutect2, varscan2
- DAB1 | c.883C>T p.P295S (on ENST00000371231; = p.P262S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64697264; called by muse, mutect2, varscan2
- DSP | c.6442G>A p.A2148T | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144539278, COSV65794417; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGR1 | c.881C>A p.A294D | Missense Mutation (SNP) | VAF 47/289 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV53521297; called by muse, mutect2, varscan2
- FANCD2 | c.2401T>C p.C801R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55045457; called by muse, mutect2, varscan2
- FLACC1 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs143899839; called by muse, mutect2, varscan2
- FRMD7 | c.1766G>T p.R589M | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770847430, COSV53745956; called by muse, mutect2, varscan2
- GABRB2 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs375083192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR141 | c.670C>G p.Q224E | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57733822, COSV57734309; called by muse, mutect2
- H2AC17 | c.176T>A p.L59Q | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58153881; called by muse, mutect2
- HCAR2 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs776840309, COSV61024387; called by muse, mutect2, varscan2
- HERC1 | c.9668G>A p.R3223Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs759638200, COSV71249916; called by muse, mutect2, varscan2
- IL1RAP | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs756041268, COSV50759136; called by muse, mutect2, varscan2
- IL34 | c.549C>A p.S183R | Missense Mutation (SNP) | VAF 68/484 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV55382402; called by muse, mutect2, varscan2
- IRAK2 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV56535231; called by muse, mutect2, varscan2
- KCNS2 | c.428G>A p.S143N | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV54640858; called by muse, mutect2, varscan2
- KLHL1 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64781364; called by muse, mutect2, varscan2
- MCM6 | c.184G>C p.V62L | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV51468935; called by muse, mutect2
- MMP13 | c.1294G>T p.D432Y | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52825458; called by muse, mutect2, varscan2
- NRXN1 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV58457619, COSV58487084; called by muse, mutect2, varscan2
- OR4A5 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs1445134544, COSV100157239, COSV60524378; called by muse, mutect2, varscan2
- PBRM1 | c.4231C>T p.R1411C (on ENST00000296302 / NM_001366071.2; = p.R1359C on NM_018313.5) | Missense Mutation (SNP) | VAF 87/558 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56300855; called by muse, mutect2, varscan2
- PDCD11 | c.1607A>G p.Y536C | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63935153; called by muse, mutect2, varscan2
- PHGDH | c.1315C>G p.Q439E | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV65572302; called by muse, mutect2, varscan2
- PRAME | c.272A>G p.H91R | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV67162362; called by muse, mutect2, varscan2
- RALYL | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs766785304, COSV72819337; called by mutect2, varscan2
- SAMD9L | c.1867A>C p.K623Q | Missense Mutation (SNP) | VAF 19/351 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.64); catalogued as COSV59084753; called by muse, mutect2
- SCN8A | c.4225G>A p.V1409I | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1272462155, COSV61991849; called by muse, mutect2
- SDK1 | c.4982T>C p.M1661T | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs775329904, COSV67386355; called by muse, mutect2
- SEMA3E | c.347C>A p.A116E | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57106023; called by muse, mutect2
- SHTN1 | c.1328A>C p.E443A | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV53386876; called by muse, mutect2, varscan2
- SPTB | c.4513G>A p.D1505N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as rs1429001823, COSV67629589; called by muse, mutect2
- SYT10 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751735974, COSV57344941; called by muse, mutect2, varscan2
- TESPA1 | c.1129G>A p.A377T (on ENST00000316577 / NM_001098815.3; = p.A239T on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV57260967; called by muse, mutect2, varscan2
- TRRAP | c.9169G>A p.A3057T (on ENST00000359863 / NM_001244580.1; = p.A3028T on NM_003496.3) | Missense Mutation (SNP) | VAF 53/367 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV62853031; called by muse, mutect2, varscan2
- TSPOAP1 | c.2252G>C p.G751A | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.189); catalogued as COSV52116545, COSV99271186; called by muse, mutect2, varscan2
- TTN | c.53458G>A p.V17820M (on ENST00000591111; = p.V10396M on NM_003319.4) | Missense Mutation (SNP) | VAF 50/299 reads (17%) | PolyPhen possibly damaging (0.907); catalogued as rs368431326, COSV60300842; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT2B11 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs775064565, COSV71423283; called by muse, mutect2, varscan2
- YY1AP1 | c.2261G>C p.G754A (on ENST00000295566 / NM_139118.2; = p.G697A on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV55121674, COSV55124443; called by muse, mutect2
- ZCWPW1 | c.1885G>A p.G629R | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.654); catalogued as rs1368756919, COSV52202266, COSV99546675; called by muse, mutect2
- SLC5A12 | c.1154del p.C385Ffs*6 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- CFAP206 | c.1581G>A p.T527= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as rs376338058; called by muse, mutect2, varscan2
- COL16A1 | c.3849C>A p.P1283= | Silent (SNP) | VAF 22/172 reads (13%) | catalogued as COSV54712913; called by muse, mutect2, varscan2
- EML2 | c.885C>T p.G295= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs779678338, COSV55603488; called by muse, mutect2, varscan2
- FGD5 | c.2373C>A p.P791= | Silent (SNP) | VAF 34/316 reads (11%) | catalogued as COSV53244848, COSV53250820; called by muse, varscan2
- GLI3 | c.4518C>T p.F1506= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as rs377186629; called by muse, mutect2, varscan2
- GPR50 | c.1704C>T p.A568= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as rs780914031, COSV54442035; called by muse, mutect2, varscan2
- HPS5 | c.2631G>A p.S877= (on ENST00000349215 / NM_181507.2; = p.S763= on NM_007216.4) | Silent (SNP) | VAF 23/138 reads (17%) | catalogued as rs765611720, COSV61687955; called by muse, mutect2, varscan2
- IMPDH2 | c.1378C>T p.L460= | Silent (SNP) | VAF 21/284 reads (7%) | catalogued as COSV58247209; called by muse, mutect2
- NEU1 | c.48G>A p.G16= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV57668964; called by muse, mutect2, varscan2
- PKHD1 | c.7068G>A p.P2356= | Silent (SNP) | VAF 32/184 reads (17%) | catalogued as rs200774031; called by muse, mutect2, varscan2
- SPTBN5 | c.4080C>T p.S1360= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs764444871, COSV58027193; called by muse, mutect2, varscan2
- TAS1R2 | c.543G>A p.L181= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV64746899; called by muse, mutect2, varscan2
- THAP4 | c.93C>T p.D31= | Silent (SNP) | VAF 41/226 reads (18%) | catalogued as COSV67192628; called by muse, mutect2, varscan2
- XIRP1 | c.1653G>A p.R551= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as COSV61140727; called by muse, mutect2, varscan2
